Somatic mutation profile of tumor specimen MMRF_2469_1_BM_CD138pos (aliquot MMRF_2469_1_BM_CD138pos_T1_KHS5U_L11075) from MMRF case MMRF_2469, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,362 days).
Specimen MMRF_2469_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c2e1c4e-6064-4bcd-9108-afe0953fb236.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2469_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2469_1_PB_CD3pos_C3_KHS5U_L11076; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6533ec31-f510-400a-b2be-e937092a624c

The open-access MAF lists 77 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 26, Missense Mutation 26, Silent 9, Intron 6, 5'Flank 4, Nonsense Mutation 2, Splice Region 1, 3'Flank 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>C p.R780T | Missense Mutation (SNP) | VAF 33/139 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 41/299 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.1612C>A p.P538T (on ENST00000506720 / NM_001322402.2; = p.P470T on NM_015236.6) | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs752311800; called by muse, mutect2, varscan2
- DAND5 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as rs541734703, COSV57684260; called by muse, mutect2, varscan2
- DSP | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 28/443 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs727505037, COSV65791851; ClinVar: uncertain significance; called by muse, mutect2
- FAT3 | c.8927G>A p.G2976D | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.994); catalogued as COSV53186866; called by muse, mutect2, varscan2
- IGLV3-21 | c.143G>C p.S48T | Missense Mutation (SNP) | VAF 76/79 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs374631730; called by muse, varscan2
- KIAA0825 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.082); catalogued as COSV56960851; called by mutect2, varscan2
- MAGEC1 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1191255686, COSV53567753, COSV53573844; called by muse, varscan2
- METTL16 | c.1246T>C p.S416P | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99563306; called by muse, mutect2, varscan2
- MROH9 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs757148581, COSV100882771; called by muse, mutect2, varscan2
- NUP210 | c.4999G>A p.V1667I | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.987); catalogued as rs1323816373; called by muse, mutect2, varscan2
- OR51G1 | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV58968729; called by muse, mutect2, varscan2
- PDE1C | c.1098A>C p.K366N | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV100374288; called by muse, mutect2, varscan2
- PDE4D | c.1087C>T p.Q363* (on ENST00000340635 / NM_001104631.2; = p.Q227* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 51/262 reads (19%) | catalogued as COSV57720843; called by muse, mutect2, varscan2
- TEK | c.1228A>G p.T410A | Missense Mutation (SNP) | VAF 119/250 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs765089230; called by muse, mutect2, varscan2
- TRPM8 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470605742, COSV61220763; called by muse, mutect2, varscan2
- UBR5 | c.3583G>C p.E1195Q | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99078624; called by muse, mutect2, varscan2
- ASPM | c.2693A>T p.D898V | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK10 | c.2599G>A p.G867S | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPAS3 | c.1821A>T p.Q607H (on ENST00000356141 / NM_001164749.2; = p.Q575H on NM_022123.3) | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PAPLN | c.2724-7T>C | Splice Region (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- PCM1 | c.3097A>T p.T1033S | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXDC2 | c.1072G>T p.G358* | Nonsense Mutation (SNP) | VAF 77/157 reads (49%) | called by muse, mutect2, varscan2
- SCUBE2 | c.423T>A p.H141Q | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.789); called by muse, varscan2
- SP8 | c.1084G>A p.G362S (on ENST00000361443 / NM_198956.4; = p.G380S on NM_182700.6) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TKTL2 | c.869C>G p.P290R | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ZNF563 | c.1431A>T p.*477Cext*2 | Nonstop Mutation (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- ZNF57 | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZNF577 | c.956T>G p.I319S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- DNA2 | c.1527C>T p.V509= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as rs1361079918; called by muse, mutect2, varscan2
- FAM126B | c.1158T>C p.D386= | Silent (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- FLT4 | c.3532C>T p.L1178= | Silent (SNP) | VAF 109/219 reads (50%) | called by muse, mutect2, varscan2
- KDM3B | c.3597A>G p.S1199= | Silent (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- MYEF2 | c.1536C>T p.S512= | Silent (SNP) | VAF 67/168 reads (40%) | catalogued as rs777919388, COSV51049068; called by muse, mutect2, varscan2
- PDZD2 | c.1377C>T p.D459= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs749089529, COSV56860954; called by muse, mutect2, varscan2
- RNF111 | c.1218T>A p.A406= | Silent (SNP) | VAF 64/124 reads (52%) | called by muse, mutect2, varscan2
- SETD5 | c.3324C>G p.S1108= | Silent (SNP) | VAF 20/231 reads (9%) | called by muse, mutect2
- ZC3HAV1 | c.1171C>T p.L391= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV99648453, COSV99648893; called by muse, mutect2
- AC100872.1 | chr8:122670530 A>G | 5'Flank (SNP) | VAF 25/173 reads (14%) | catalogued as rs1254909849; called by muse, mutect2, varscan2
- ACOT11 | c.*3504A>C | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by mutect2, varscan2
- AHR | c.*1542A>G | 3'UTR (SNP) | VAF 8/39 reads (21%) | called by mutect2, varscan2
- ARFIP1 | c.*1370_*1372dup | 3'UTR (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- ATF4 | c.-697G>A | 5'UTR (SNP) | VAF 15/89 reads (17%) | called by muse, varscan2
- BCL7A | c.*1659C>T | 3'UTR (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- BNC2 | chr9:16870721 C>G | 5'Flank (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- CACNA1E | c.*6545G>A | 3'UTR (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- CAPN2 | c.*1011A>C | 3'UTR (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- CASP16P | chr16:3147878 C>T | 3'Flank (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- CMTM6 | c.*562T>A | 3'UTR (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- DIPK2B | c.*2152C>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | catalogued as rs1292289861, COSV101211656; called by muse, mutect2
- DVL3 | c.*1672T>G | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- ERLIN2 | c.*4255C>G | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- ESYT3 | c.915+122G>T | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as rs200430059; called by mutect2, varscan2
- FARP2 | c.1893+1654C>T | Intron (SNP) | VAF 83/587 reads (14%) | called by muse, mutect2, varscan2
- FNBP1 | c.*2607G>A | 3'UTR (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- FRMD3 | c.*2774G>A | 3'UTR (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- FYCO1 | c.*1708A>T | 3'UTR (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- GJB7 | c.*859C>T | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- GLIS3 | c.*2168dup | 3'UTR (INS) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- GPR179 | chr17:38343886 T>G | 5'Flank (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- GRK5 | c.*153A>G | 3'UTR (SNP) | VAF 39/341 reads (11%) | called by muse, varscan2
- HMOX1 | chr22:35380939 ins A | 5'Flank (INS) | VAF 22/163 reads (13%) | called by mutect2, pindel, varscan2
- KIF13B | c.*1837G>A | 3'UTR (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- KLHL14 | c.-43-372G>A | Intron (SNP) | VAF 15/240 reads (6%) | called by muse, mutect2
- LONP2 | c.*4842A>T | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, varscan2
- LRRC8C | c.*1110A>G | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- NDC1 | c.*587C>T | 3'UTR (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*2286C>T | 3'UTR (SNP) | VAF 4/70 reads (6%) | catalogued as rs1242916426; called by muse, mutect2
- OR51F2 | c.*3G>C | 3'UTR (SNP) | VAF 150/654 reads (23%) | called by muse, mutect2, varscan2
- OXGR1 | c.*396T>C | 3'UTR (SNP) | VAF 18/96 reads (19%) | catalogued as rs537131322; called by muse, mutect2, varscan2
- PSKH1 | c.*477A>G | 3'UTR (SNP) | VAF 96/209 reads (46%) | called by muse, varscan2
- RBM38 | c.238-256G>A | Intron (SNP) | VAF 15/44 reads (34%) | catalogued as rs1352377842; called by muse, mutect2, varscan2
- SATB2 | c.*840G>A | 3'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs961620761; called by mutect2, varscan2
- SPIDR | c.1545-61C>G | Intron (SNP) | VAF 11/229 reads (5%) | called by muse, mutect2
- TBC1D15 | c.*2528G>A | 3'UTR (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- TFB1M | c.133+25G>A | Intron (SNP) | VAF 42/80 reads (53%) | catalogued as rs1225764121; called by muse, varscan2
